Gene-level copy-number profile of tumor specimen C3L-02665-01 (profiled together with C3L-02665-02, C3L-02665-03, C3L-02665-04, C3L-02665-05) from CPTAC case C3L-02665, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 51.1 years (18,659 days).
Specimen C3L-02665-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5e133ed5-d0f7-4bd9-ada0-fbb0923a001c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02665-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/9c73eff7-4799-4028-8c07-11c2806c7066

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 486; copy number 1: 2,578; copy number 2: 24,819; copy number 3: 17,538; copy number 4: 7,490; copy number 5: 3,607; copy number 6: 2,039; copy number 7: 254; copy number 8: 64; copy number 11: 23.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes: AC239859.2, LINC02799.
- chr1:145,095,974–145,169,664, 2 genes: FAM72D, RNU1-153P.
- chr4:68,614,419–68,628,899, 3 genes (within-gene range 0–1): AC147055.2, AC147055.4, AC147055.3.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr22:25,564,675–25,729,294, 4 genes (within-gene range 0–1): GRK3, AL022329.2, YES1P1, RNA5SP494.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,987 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:23,018,125–23,381,299, 5 genes, copy number 6: AC018467.1, AC012506.1, AC012506.3, AC012506.2, AC012506.4.
- chr2:139,824,896–140,221,485, 6 genes, copy number 7: AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr3:57,548,838–59,050,084, 32 genes, copy number 6: RNU6-483P, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT, SLMAP, PDHA1P1, PPIAP16, FLNB, FLNB-AS1, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1, FAM107A, AC119424.1, FAM3D-AS1, FAM3D, CFAP20DC, CFAP20DC-AS1.
- chr4:70,334,981–70,410,195, 4 genes, copy number 7: CABS1, SMR3A, SMR3B, OPRPN.
- chr5:10,564,070–19,234,487, 121 genes, copy number 6 (broad region; genes not listed).
- chr5:20,606,710–45,895,970, 332 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr6:62,460,940–63,779,336, 19 genes, copy number 6–7 (within-gene range 2–7): DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr7:37,032–56,323,601, 951 genes, copy number 5 (broad region; genes not listed).
- chr7:62,275,361–116,798,377, 1,019 genes, copy number 5–6 (broad region; genes not listed).
- chr11:46,602,861–54,725,816, 142 genes, copy number 5–6 (broad region; genes not listed).
- chr11:55,819,607–55,858,547, 4 genes, copy number 7: OR5D18, OR5L2, OR5D16, OR9M1P.
- chr12:96,900,697–122,422,632, 566 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:123,633,739–124,316,024, 24 genes, copy number 5 (within-gene range 4–5): GTF2H3, AC117503.3, AC117503.2, TCTN2, AC117503.1, ATP6V0A2, AC117503.5, RPL27P12, AC117503.4, DNAH10, CCDC92, DNAH10OS, AC068790.7, AC068790.4, AC068790.3, AC068790.2, AC068790.5, AC068790.6, ZNF664, AC068790.8, RFLNA, AC068790.1, AC068790.9, AC026358.1.
- chr14:34,485,979–41,904,549, 125 genes, copy number 5–7 (broad region; genes not listed).
- chr14:43,540,883–64,387,986, 373 genes, copy number 5 (broad region; genes not listed).
- chr16:17,825,252–31,711,986, 535 genes, copy number 5 (broad region; genes not listed).
- chr16:57,735,739–57,971,128, 7 genes, copy number 6: KATNB1, KIFC3, AC092118.2, MIR6772, AC092118.1, RNU6-20P, CNGB1.
- chr16:64,943,753–65,126,112, 1 gene, copy number 7 (within-gene range 2–7): CDH11.
- chr16:66,366,622–67,009,758, 36 genes, copy number 6 (within-gene range 3–6): CDH5, LINC00920, BEAN1, AC132186.1, BEAN1-AS1, AC010542.3, TK2, AC010542.2, AC010542.4, Y_RNA, CKLF, CKLF-CMTM1, AC010542.5, CMTM1, CMTM2, AC010542.1, CMTM3, CMTM4, DYNC1LI2, AC018557.1, AC018557.3, AC018557.2, AC044802.1, TERB1, NAE1, AC044802.2, CA7, PDP2, CDH16, RRAD, CIAO2B, CES2, AC009084.1, AC009084.3, CES3, CES4A.
- chr16:68,264,516–70,660,682, 97 genes, copy number 6–8 (broad region; genes not listed).
- chr16:71,845,976–72,112,912, 15 genes, copy number 6 (within-gene range 2–6): ATXN1L, IST1, AC010653.2, ZNF821, AC009127.1, PKD1L3, RPL39P31, AC009127.2, ATP5F1AP3, DHODH, TXNL4B, HP, HPR, AC009087.1, DHX38.
- chr16:89,490,719–90,222,851, 38 genes, copy number 6: SPG7, AC092123.1, RPL13, SNORD68, CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:20,647,287–22,706,703, 73 genes, copy number 6–11 (broad region; genes not listed).
- chr17:47,200,446–50,948,750, 196 genes, copy number 7 (broad region; genes not listed).
- chr17:51,630,313–53,106,358, 6 genes, copy number 6: CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40.
- chr17:62,699,244–64,662,307, 78 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:66,964,707–68,763,882, 58 genes, copy number 6: CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2.
- chr17:68,944,531–70,779,230, 28 genes, copy number 6 (within-gene range 2–6): ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1.
- chr17:72,290,091–73,312,005, 20 genes, copy number 6: LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4.
- chr17:74,213,571–74,372,622, 7 genes, copy number 6: TTYH2, AC100786.1, DNAI2, AC103809.1, KIF19, BTBD17, GPR142.
- chr17:76,950,317–77,217,101, 9 genes, copy number 6 (within-gene range 3–6): AC016168.2, AC016168.1, AC016168.3, Metazoa_SRP, SNHG20, SEC14L1, SCARNA16, MIR6516, RNU4-47P.
- chr17:79,089,345–79,516,148, 1 gene, copy number 5 (within-gene range 1–5): RBFOX3.
- chr17:79,598,032–82,057,470, 133 genes, copy number 5 (broad region; genes not listed).
- chr17:82,228,397–83,240,804, 51 genes, copy number 5–6: SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750, AC087222.1, B3GNTL1, AC130371.1, METRNL, AC130371.2, AC144831.1, AC139099.3, AC139099.2, AC139099.1, RPL23AP87.
- chr19:13,823,880–20,127,076, 350 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:20,125,044–20,151,908, 3 genes, copy number 6 (within-gene range 4–6): AC011447.1, AC011447.2, BNIP3P15.
- chr19:30,850,975–40,950,660, 442 genes, copy number 5–6 (broad region; genes not listed).
- chr22:41,922,032–42,649,392, 38 genes, copy number 5: TNFRSF13C, MIR378I, CENPM, LINC00634, SEPTIN3, Z99716.1, WBP2NL, SLC25A5P1, NAGA, PHETA2, SNORD13P1, SMDT1, NDUFA6, AL021878.4, NDUFA6-DT, OLA1P1, CYP2D6, AC254562.1, AC254562.2, AC254562.3, CYP2D7, CYP2D8P, TCF20, OGFRP1, LINC01315, NFAM1, AL022316.1, SERHL, RRP7A, SERHL2, RRP7BP, RN7SKP80, RNU6-513P, POLDIP3, RNU12, Z93241.1, CYB5R3, ATP5MGL.
- chr22:44,566,965–46,057,210, 39 genes, copy number 5 (within-gene range 3–5): KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1, AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1.
- chr22:46,055,740–46,058,160, 1 gene, copy number 5 (within-gene range 3–5): AL121672.1.

Autosomal genes at a single copy (total copy number 1): 2,535. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
